Surgical pathology report (de-identified scan), TCGA case TCGA-DS-A0VL, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-DS-A0VL-01A (Primary Tumor).

[page 1 of 3]
Site: cervix, NOS
053.9

8070/3

12/7/10
lw

Case is (Link):		

Date of Service: '

Pathology Report

RT **

ORDERING PHYSICIAN:

Case:

COLLECTED:

RECEIVED:

CLINICAL INFORMATION:

Patient is a year old female with history of CIN 3 on biopsy and a recent pregnancy.

FINAL DIAGNOSIS:

UTERUS AND CERVIX (HYSTERECTOMY):

- Invasive squamous cell carcinoma, moderately differentiated-
- Depth of invasion 0.4 cm out 2.0 cm cervical thickness
- Extensive lymphovascular invasion.
- Posterior radial soft tissue margin 0.9 cm
- No invasive tumor on sections from the anterior cervix
- Closest vaginal margin 2 cm
- Parametria are negative for malignancy
- Decidualized endometrium and myometrium, consistent with history of recent pregnancy

LYMPH NODE, RIGHT PELVIC (BIOPSY):

- Two lymph nodes negative for carcinoma (0/2)

LYMPH NODE, RIGHT PERIAORTIC (BIOPSY):

- One lymph node negative for carcinoma (0/1)

LYMPH NODE, LEFT PELVIC (BIOPSY):

- Four lymph nodes negative for carcinoma (0/4)

LYMPH NODES, LEFT PERIAORTIC (BIOPSY):

- One lymph node negative for carcinoma (0/1)

MICROSCOPIC EXAM:

Sections of the cervical tumor show nests of malignant cells. The nests appear to be infiltrating cervical glands and there are bands of collagen surrounding many of the nests. The malignant cells are somewhat radially located around the edges of the nests. Central necrosis within the

[page 2 of 3]
nests is prominent. The tumor cells have a high nuclear to cytoplasmic ratio with nuclei containing loose chromatin and small nucleoli. Mitotic figures are abundant.

GROSS DESCRIPTION:

The specimen is received fresh in five containers bearing the patient's name and hospital number.

Part #1, labeled "uterus and cervix," consists of a 1128-gm uterus and cervix with no attached adnexa. The uterus measures 14.5 cm from cornu to cornu, 17 cm from cervical os to top of fundus, and 9 cm from anterior to posterior. A probe extends into the cervical os 14.5. The cervix is round with a defect in the posterior 6 o'clock position. The defect appears to be within a lesion that is 3.5 cm from lateral to lateral and is 2 cm from anterior to posterior and involves the entire posterior aspect of the cervix. The defect appears as a chunk out of this lesion that is 1.5 cm deep and 1.5 cm on its side. The cervix itself is 5 cm from lateral to lateral and 4 cm anterior to posterior. There is 2 cm of attached vaginal wall that is attached from the 6 o'clock to the 9 o'clock position. On the anterior and left side there is approximately 1 cm of attached vaginal wall. The serosa on the uterus is pink and unremarkable. The left parametrium is inked with black ink and the right parametrium is inked with green ink. Upon opening the uterus, the cervical canal measures 3.5 cm and the endometrial cavity is 10.5 cm vertically and 7 cm at its widest point. The endometrial cavity is covered with a boggy, hemorrhagic-appearing endometrium. The myometrium is thick and boggy-appearing. The maximum thickness is 3.5 cm. The cervix is dissected away from the specimen and entirely submitted as follows:

A1-A6	12 o'clock to 3 o'clock
A7-A13	3 o'clock to 6 o'clock
A14-A24	6 o'clock to 9 o'clock
A25-A30	9 o'clock to 12 o'clock
A31-A36	right parametrium
A37-A39	left parametrium
A40-A47	uterus

Part #2, labeled "right pelvic lymph node," consists of two fragments of fibroadipose tissue. The first piece is 1.5 x 1 x 0.7 cm and the second is 2.1 x 1.5 x 0.5 cm. The specimen is entirely submitted in cassettes B1 and B2.

Part #3, labeled "right periaortic," consists of one lymph node that is 2 x 1.2 x 0.8 cm and another small piece of fibroadipose tissue that is 1 x 0.3 x 0.2 cm. The specimen is entirely submitted in cassettes C1.

Part #4, labeled "left pelvic lymph node," consists of a fragment of fibroadipose tissue that is 2.5 x 0.7 x 1.2 cm. The specimen is bisected and entirely submitted in cassettes D1 and D2.

Part #5, labeled "left periaortic lymph nodes," consists of one piece of fibroadipose tissue that is 1.1 x 0.9 x 0.5 cm. The specimen is entirely submitted in cassette E1.

[page 3 of 3]
By his/her/their electronic signature(s), the senior pathologist(s) certifies that he/she/they personally conducted a gross and/or microscopic examination(s) of the described specimen(s) and made the diagnosis(es) juxtaposed with his/her/their electronic signature.

M.D.

Electronically signed

M.D.

Dictated:

By: M.D.

Reference number:

Received:

Document ID Number:

*** END OF

Source: NCI Genomic Data Commons file 2a299139-2666-4972-a671-a8e315b39808 (TCGA-DS-A0VL.89391955-6647-4F46-969D-9AC4205B2D9C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).